Somatic mutation profile of tumor specimen ALCH-AEKT-TTP1-A (aliquot ALCH-AEKT-TTP1-A-8-0-D-A627-36) from ALCHEMIST case ALCH-AEKT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.9 years (18,965 days).
Specimen ALCH-AEKT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5196af28-e161-463a-a9ae-39438fa57160.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKT-NB1-A (Blood Derived Normal), aliquot ALCH-AEKT-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/963d4e52-3c74-447d-baaf-c9a0166664dd

The open-access MAF lists 101 somatic variants for this specimen: 72 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 19, Intron 10, Nonsense Mutation 5, Splice Region 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 44/408 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 13/163 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- ATP1B4 | c.912+1G>C p.X304_splice (on ENST00000218008 / NM_001142447.3; = p.X300_splice on NM_012069.5) | Splice Site (SNP) | VAF 24/288 reads (8%) | catalogued as COSV54313550; called by muse, mutect2
- CHRM2 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 19/357 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV57767588; called by muse, mutect2
- COL3A1 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV58588611; called by muse, mutect2
- CRISP1 | c.26T>C p.L9S | Missense Mutation (SNP) | VAF 28/486 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1045779797; called by muse, mutect2
- KRTAP27-1 | c.162C>G p.C54W | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV67001570; called by muse, mutect2, varscan2
- MN1 | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV56560418; called by muse, mutect2
- MPP1 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV65729624; called by muse, mutect2
- MYO3A | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 50/504 reads (10%) | catalogued as COSV99780455; called by muse, mutect2
- NPY1R | c.528C>A p.Y176* | Nonsense Mutation (SNP) | VAF 13/236 reads (6%) | catalogued as COSV99648426; called by muse, mutect2
- NRXN1 | c.156C>G p.S52R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV68039053; called by muse, mutect2
- OR4P4 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58921589; called by muse, mutect2, varscan2
- PBX2 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100904083; called by muse, mutect2, varscan2
- PCDH15 | c.2868+6T>A | Splice Region (SNP) | VAF 54/589 reads (9%) | catalogued as COSV100216527; called by muse, mutect2
- PCDHA3 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 32/401 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs544698058; called by muse, mutect2
- PLK1 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55621175; called by muse, mutect2, varscan2
- PTPRZ1 | c.5171T>A p.L1724Q | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66446227; called by muse, mutect2
- RYR2 | c.3560G>T p.G1187V | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100769002; called by muse, mutect2, varscan2
- SLC4A4 | c.708G>T p.R236S (on ENST00000264485 / NM_001098484.3; = p.R192S on NM_003759.4) | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as COSV52635863; called by muse, mutect2, varscan2
- SV2A | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs149927876, COSV64964911; called by muse, mutect2
- TBX20 | c.222C>G p.S74R | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV101282356; called by muse, mutect2, varscan2
- TEX13A | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs782469368; called by muse, mutect2
- TRPS1 | c.3187G>A p.E1063K (on ENST00000220888 / NM_001330599.2; = p.E1076K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/795 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV55268434, COSV99631195; called by muse, mutect2
- ZNF267 | c.1045C>G p.P349A | Missense Mutation (SNP) | VAF 29/426 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56252753; called by muse, mutect2
- AAK1 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ABCB1 | c.24T>A p.N8K | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ACE | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2
- ACSM5 | c.1437C>G p.S479R | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- C9 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- CLIC2 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 42/548 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL22A1 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- DCP1B | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- DEFB132 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 48/558 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- DOCK10 | c.5698G>C p.E1900Q | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- ETV3L | c.995C>G p.P332R | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); called by muse, mutect2
- EXOC6 | c.1205C>A p.T402N | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FSCB | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 26/410 reads (6%) | called by muse, mutect2
- HEPH | c.118G>T p.A40S (on ENST00000343002; = p.A94S on NM_138737.5) | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.391); called by muse, mutect2
- HMGCLL1 | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KAZN | c.1795C>G p.R599G | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2
- LAMA2 | c.6007G>T p.E2003* | Nonsense Mutation (SNP) | VAF 32/412 reads (8%) | called by muse, mutect2
- LONRF3 | c.1572G>T p.E524D (on ENST00000371628 / NM_001031855.3; = p.E483D on NM_024778.5) | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2
- MPDZ | c.3614G>A p.G1205E | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRPL24 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2
- OR2B6 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.156); called by muse, mutect2
- PCDHA3 | c.1714G>T p.G572C | Missense Mutation (SNP) | VAF 33/402 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- PDHA2 | c.452T>C p.M151T | Missense Mutation (SNP) | VAF 34/419 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- PEG3 | c.4321G>T p.G1441* | Nonsense Mutation (SNP) | VAF 30/353 reads (8%) | called by muse, mutect2
- PJA1 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.968); called by muse, mutect2
- PLCE1 | c.4434C>G p.D1478E | Missense Mutation (SNP) | VAF 55/549 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRICKLE2 | c.2119G>T p.G707C (on ENST00000295902; = p.G651C on NM_198859.4) | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); called by muse, mutect2
- PRLR | c.1434G>T p.E478D | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PRSS35 | c.557T>A p.V186E | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RELL2 | c.504-7C>A | Splice Region (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2
- RYR2 | c.14307A>T p.L4769F | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2
- SCN10A | c.3305C>A p.P1102H | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLX4 | c.1347G>T p.E449D | Missense Mutation (SNP) | VAF 42/502 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- SPRY3 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- TAS2R42 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TAS2R60 | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 30/435 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2
- TCEAL1 | c.342A>T p.R114S | Missense Mutation (SNP) | VAF 60/613 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMPRSS15 | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- TRBV3-1 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIM58 | c.852G>C p.E284D | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2
- TRIM58 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UNC79 | c.4570G>T p.D1524Y (on ENST00000393151 / NM_001346218.2; = p.D1347Y on NM_020818.5) | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WDFY4 | c.1819G>T p.V607L | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.07); called by muse, mutect2
- WNK2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WRAP73 | c.516G>T p.R172= | Splice Region (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2
- YY2 | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- ZNF677 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ANGPT1 | c.1020C>T p.G340= | Silent (SNP) | VAF 36/331 reads (11%) | catalogued as COSV52446410; called by muse, mutect2, varscan2
- APPBP2 | c.27C>T p.I9= | Silent (SNP) | VAF 16/207 reads (8%) | catalogued as rs761407673; called by muse, mutect2
- BDH1 | c.297G>T p.L99= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- CBX4 | c.426G>A p.P142= | Silent (SNP) | VAF 22/327 reads (7%) | catalogued as rs1441012634; called by muse, mutect2
- CNTNAP5 | c.1143C>A p.P381= | Silent (SNP) | VAF 27/274 reads (10%) | catalogued as COSV70477851, COSV70501264; called by muse, mutect2
- FSIP2 | c.1266T>A p.G422= | Silent (SNP) | VAF 25/292 reads (9%) | called by muse, mutect2
- GLUD2 | c.654C>A p.G218= | Silent (SNP) | VAF 50/735 reads (7%) | catalogued as rs746028809; called by muse, mutect2
- GOLGA8J | c.954G>A p.V318= | Silent (SNP) | VAF 34/707 reads (5%) | called by muse, mutect2
- GPCPD1 | c.219T>C p.F73= | Silent (SNP) | VAF 19/208 reads (9%) | called by muse, mutect2
- IL27RA | c.144C>G p.G48= | Silent (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- KIAA1217 | c.3900G>T p.T1300= | Silent (SNP) | VAF 31/388 reads (8%) | called by muse, mutect2
- KIN | c.696G>A p.T232= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as rs747671134, COSV101092482; called by muse, mutect2
- LRIG2 | c.1215A>T p.A405= | Silent (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- LYST | c.9958C>A p.R3320= | Silent (SNP) | VAF 38/470 reads (8%) | catalogued as COSV101089810; called by muse, mutect2
- NID1 | c.918G>A p.E306= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as COSV99937111; called by muse, mutect2, varscan2
- RP1L1 | c.939C>A p.V313= | Silent (SNP) | VAF 18/400 reads (5%) | called by muse, mutect2
- RTN4 | c.1128G>T p.V376= | Silent (SNP) | VAF 25/329 reads (8%) | called by muse, mutect2
- WNK3 | c.5205A>G p.G1735= | Silent (SNP) | VAF 18/257 reads (7%) | called by muse, mutect2
- ZNF831 | c.1524C>T p.P508= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- ARMCX4 | c.1039-3653C>G | Intron (SNP) | VAF 26/422 reads (6%) | called by muse, mutect2
- GNG2 | c.87+1168G>T | Intron (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- HDAC6 | c.2188-208T>A | Intron (SNP) | VAF 13/195 reads (7%) | called by muse, mutect2
- KCNT2 | c.2349-1198G>A | Intron (SNP) | VAF 20/158 reads (13%) | called by muse, varscan2
- KDM6A | c.3548+31A>T | Intron (SNP) | VAF 32/346 reads (9%) | catalogued as rs776317091; called by muse, mutect2
- LILRB5 | c.34+32C>T | Intron (SNP) | VAF 7/66 reads (11%) | catalogued as rs187327837; called by muse, mutect2, varscan2
- P2RX1 | c.137+617G>A | Intron (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- RNF217 | c.1556-309G>T | Intron (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- THEM4 | c.287-809C>T | Intron (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- WDR25 | c.822+369C>T | Intron (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
